Somatic mutation profile of tumor specimen TCGA-50-6595-01A (aliquot TCGA-50-6595-01A-12D-1855-08) from TCGA case TCGA-50-6595, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 74.5 years (27,197 days).
Specimen TCGA-50-6595-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3402b3fd-ce3d-4f5c-9fcd-c5670efacf4c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-6595-11A (Solid Tissue Normal), aliquot TCGA-50-6595-11A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63b1b642-8519-454d-b81b-5a2ce519e96b

The open-access MAF lists 81 somatic variants for this specimen: 66 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 14, Nonsense Mutation 3, Splice Region 2, Frame Shift Del 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2156G>C p.G719A | Missense Mutation (SNP) | VAF 26/89 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913428, COSV51769339, COSV51771914, COSV51779524; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2303G>T p.S768I | Missense Mutation (SNP) | VAF 39/157 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913465, COSV51768106, COSV51821681, COSV51833841; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.3475C>A p.Q1159K | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55289211; called by muse, mutect2
- ABCA12 | c.1601C>G p.P534R (on ENST00000272895 / NM_173076.3; = p.P216R on NM_015657.3) | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.607); catalogued as COSV55955802; called by muse, mutect2, varscan2
- ABCB4 | c.2897G>C p.G966A | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.506); catalogued as COSV55934246; called by muse, mutect2
- ACE | c.1210C>G p.L404V | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.165); catalogued as rs1229622121, COSV52005686, COSV99326994; called by muse, mutect2
- ACOX3 | c.722G>A p.G241E | Missense Mutation (SNP) | VAF 40/364 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62711644, COSV62712864; called by muse, mutect2
- ADGRL1 | c.3841G>A p.E1281K (on ENST00000340736 / NM_001008701.3; = p.E1276K on NM_014921.5) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100529627; called by muse, mutect2
- AKR7A3 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs781498992, COSV64389223; called by muse, mutect2, varscan2
- BAG3 | c.610G>T p.G204W | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100958250; called by mutect2, varscan2
- BRINP3 | c.1393A>T p.T465S | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as COSV66520584; called by muse, mutect2
- CA1 | c.571G>C p.D191H | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.203); catalogued as rs867795228, COSV56278242; called by muse, mutect2
- CCR6 | c.763G>C p.V255L | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV100551133; called by muse, mutect2
- CDC42BPG | c.1678C>G p.Q560E | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.93); catalogued as COSV61346841; called by muse, mutect2, varscan2
- CDCA7 | c.493C>T p.P165S (on ENST00000347703 / NM_145810.3; = p.P244S on NM_031942.5) | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.052); catalogued as COSV60720255; called by muse, mutect2, varscan2
- CDKN2A | c.64del p.R22Gfs*4 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | catalogued as CM1515139; called by pindel, varscan2
- CEP85L | c.510G>T p.Q170H | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV63822256; called by muse, mutect2, varscan2
- DNAH6 | c.1991G>C p.R664T | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV52857066, COSV52879547; called by muse, mutect2, varscan2
- DNMT3A | c.979T>G p.W327G | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53048214; called by muse, mutect2, varscan2
- DSG2 | c.691-2A>G p.X231_splice | Splice Site (SNP) | VAF 8/42 reads (19%) | catalogued as COSV55198409; called by muse, mutect2, varscan2
- ETNPPL | c.1308A>T p.L436F | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV56595493; called by muse, mutect2
- GLI2 | c.427T>A p.S143T | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV58039730; called by muse, mutect2, varscan2
- GPR34 | c.354C>G p.N118K | Missense Mutation (SNP) | VAF 10/249 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV100587381; called by muse, mutect2
- GPR52 | c.104G>C p.S35T | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV52289580; called by muse, mutect2, varscan2
- GRM1 | c.3461C>T p.S1154L | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as rs768961389, COSV51130267; called by muse, mutect2, varscan2
- GTPBP1 | c.595C>T p.H199Y | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53284167; called by muse, varscan2
- GZF1 | c.648C>A p.Y216* | Nonsense Mutation (SNP) | VAF 11/73 reads (15%) | catalogued as COSV100582586; called by muse, mutect2
- H2AC21 | c.179C>G p.T60S | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.044); catalogued as COSV100480017; called by muse, mutect2, varscan2
- KAT6B | c.3674A>G p.N1225S | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.006); catalogued as rs1564630357, COSV54745467; called by muse, mutect2
- KCNA7 | c.550G>A p.G184S | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs757480933, COSV99671832, COSV99671956; called by muse, mutect2, varscan2
- LRP1B | c.5647T>C p.Y1883H | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67207396; called by muse, mutect2, varscan2
- LRRC66 | c.2606C>A p.A869D | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.019); catalogued as COSV58633112, COSV58633486; called by muse, mutect2
- MTHFD1 | c.2147G>A p.G716E | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53699655; called by muse, mutect2
- MYO16 | c.3181C>T p.Q1061* | Nonsense Mutation (SNP) | VAF 10/146 reads (7%) | catalogued as COSV62746747; called by muse, mutect2
- NAALAD2 | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV58960234, COSV58966950; called by muse, mutect2
- NCOA7 | c.2816G>C p.W939S | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99997284; called by muse, mutect2, varscan2
- NLRP3 | c.2055G>C p.M685I | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV60222768; called by muse, mutect2
- NME8 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as COSV52249179; called by muse, mutect2
- NRIP1 | c.1907A>G p.Q636R | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100012824; called by muse, mutect2
- ODF2 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); catalogued as rs1222192792, COSV63546585; called by muse, mutect2
- PARP8 | c.1668G>A p.Q556= | Splice Region (SNP) | VAF 3/42 reads (7%) | catalogued as COSV55858954; called by muse, mutect2
- PCDHA6 | c.1067C>T p.S356F | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.262); catalogued as COSV65351331; called by muse, mutect2
- PGAP4 | c.1183C>T p.R395W | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769427864, COSV66387506, COSV66388440; called by muse, mutect2, varscan2
- PHC3 | c.1882T>G p.L628V (on ENST00000494943 / NM_001308116.2; = p.L640V on NM_024947.4) | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV71948582; called by muse, mutect2
- PKD1 | c.4574T>G p.V1525G | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV51914252; called by muse, mutect2, varscan2
- PLCB3 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV54187731; called by muse, mutect2
- PNLIP | c.68G>A p.R23K | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV65040193; called by muse, mutect2
- POM121 | c.1544G>A p.R515Q (on ENST00000434423; = p.R250Q on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); catalogued as rs566381910, COSV99988647; called by muse, mutect2, varscan2
- RNF6 | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as COSV60418565; called by muse, mutect2, varscan2
- ROBO1 | c.4814G>A p.S1605N | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.275); catalogued as COSV71392215, COSV71393405; called by muse, mutect2
- RP2 | c.449G>A p.W150* | Nonsense Mutation (SNP) | VAF 6/90 reads (7%) | catalogued as CM013031, COSV54461530; called by muse, mutect2
- SLC7A2 | c.1674T>C p.V558= (on ENST00000494857 / NM_001370338.1; = p.V597= on NM_003046.6) | Splice Region (SNP) | VAF 6/134 reads (4%) | catalogued as COSV50250897; called by muse, mutect2
- SLITRK4 | c.1875A>T p.L625F | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62022742; called by muse, mutect2, varscan2
- SMCR8 | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 29/214 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58176703; called by muse, mutect2, varscan2
- SORCS1 | c.3109C>A p.L1037I | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV53858104; called by muse, mutect2, varscan2
- SPOCD1 | c.2074C>A p.L692M | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57095730; called by muse, mutect2, varscan2
- TEKT3 | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs148345040; called by muse, mutect2, varscan2
- TEX10 | c.1063G>A p.V355I | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.053); catalogued as COSV66515037; called by muse, mutect2, varscan2
- TEX11 | c.799G>A p.V267I (on ENST00000344304; = p.V252I on NM_031276.3) | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV60229332; called by muse, mutect2
- TLR4 | c.2232C>A p.S744R (on ENST00000355622 / NM_138554.5; = p.S704R on NM_003266.4) | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62923005; called by muse, mutect2, varscan2
- TNPO2 | c.2212G>A p.A738T | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV63508039; called by muse, mutect2, varscan2
- TTC14 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 35/311 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.728); catalogued as COSV56010629; called by muse, mutect2, varscan2
- TUBGCP6 | c.2473G>T p.V825L | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV50541767; called by muse, mutect2, varscan2
- ZBTB10 | c.1923G>T p.L641F | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.648); catalogued as COSV66947201; called by muse, mutect2, varscan2
- ZNF304 | c.1861G>C p.G621R | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56583997; called by muse, mutect2, varscan2
- ZNF428 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); catalogued as COSV100334841; called by muse, mutect2, varscan2
- ACSL6 | c.1044C>T p.I348= (on ENST00000379240; = p.I373= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV57296550; called by muse, mutect2, varscan2
- AKAP12 | c.1140C>A p.P380= | Silent (SNP) | VAF 5/67 reads (7%) | catalogued as rs1337164817, COSV53573415; called by muse, mutect2
- C11orf1 | c.24C>T p.C8= | Silent (SNP) | VAF 56/451 reads (12%) | catalogued as COSV52788062; called by muse, mutect2, varscan2
- CEP128 | c.2121G>T p.V707= | Silent (SNP) | VAF 44/224 reads (20%) | catalogued as COSV55373943, COSV55376402; called by muse, mutect2, varscan2
- H1-4 | c.189G>A p.K63= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as rs535188796, COSV56800659, COSV99175386; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNMA1 | c.3006C>T p.I1002= (on ENST00000286628 / NM_001161352.2; = p.I944= on NM_002247.4) | Silent (SNP) | VAF 16/286 reads (6%) | catalogued as COSV54242038; called by muse, mutect2
- KLHL20 | c.1281C>T p.L427= | Silent (SNP) | VAF 9/173 reads (5%) | catalogued as COSV52941384, COSV99268656; called by muse, mutect2
- NLRP5 | c.1980G>C p.G660= | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as COSV101173315, COSV66763775, COSV66764886; called by muse, mutect2, varscan2
- OR2T11 | c.379C>T p.L127= | Silent (SNP) | VAF 5/98 reads (5%) | catalogued as COSV58185519, COSV58187089; called by muse, mutect2
- POLR2H | c.13C>T p.L5= | Silent (SNP) | VAF 16/125 reads (13%) | catalogued as rs752698223, COSV55600573, COSV55601316; called by muse, mutect2, varscan2
- RFXANK | c.729G>A p.E243= | Silent (SNP) | VAF 6/138 reads (4%) | catalogued as COSV57393482; called by muse, mutect2
- ZNF226 | c.2205C>T p.V735= | Silent (SNP) | VAF 14/171 reads (8%) | catalogued as COSV56196469; called by muse, mutect2
- ZNF473 | c.537A>T p.T179= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as COSV99568937; called by muse, mutect2, varscan2
- ZNF827 | c.1851C>T p.F617= | Silent (SNP) | VAF 9/136 reads (7%) | catalogued as COSV65226315; called by muse, mutect2
- FMN1 | c.2044-1732G>A | Intron (SNP) | VAF 10/146 reads (7%) | catalogued as COSV57921398; called by muse, mutect2
